Somatic mutation profile of tumor specimen 0DFXGH from CCDI case PBBRZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.8 years (2,117 days).
Specimen 0DFXGH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b05c269-c2e9-4564-8054-2de3885be188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82e261a8-9d2f-4354-92d6-ffa2e08faf1e

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 2, Intron 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMGB3 | c.160G>A p.G54R | Missense Mutation (SNP) | VAF 111/431 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs968817522; called by muse, mutect2, varscan2
- PDE4DIP | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 212/852 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs782773952, COSV57694344; called by muse, mutect2, varscan2
- BCOR | c.4725_4733del p.M1575_F1578delinsI (on ENST00000378444 / NM_001123385.2; = p.M1541_F1544delinsI on NM_017745.6) | In Frame Del (DEL) | VAF 128/497 reads (26%) | called by mutect2, varscan2
- BRCA1 | c.2094A>C p.P698= | Silent (SNP) | VAF 226/670 reads (34%) | called by muse, mutect2, varscan2
- RSPH6A | c.1236C>T p.P412= | Silent (SNP) | VAF 118/304 reads (39%) | catalogued as rs773950083, COSV55574742; called by muse, mutect2, varscan2
- ZNF679 | c.453C>A p.T151= | Silent (SNP) | VAF 220/656 reads (34%) | called by mutect2, varscan2
- OTOP2 | c.643+81G>A | Intron (SNP) | VAF 4/44 reads (9%) | catalogued as rs971689025; called by muse, varscan2
- ZFYVE16 | c.3607+79C>T | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, varscan2
